Somatic mutation profile of tumor specimen TCGA-WC-A885-01A (aliquot TCGA-WC-A885-01A-11D-A39W-08) from TCGA case TCGA-WC-A885, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.2 years (21,978 days).
Specimen TCGA-WC-A885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5522d7f-64c7-46e7-b94f-28cf7bf11681.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A885-10A (Blood Derived Normal), aliquot TCGA-WC-A885-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecfa8365-3695-4bb2-b396-a4b068ed8357

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 38/81 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMZ1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs754107925; called by muse, mutect2, varscan2
- BAZ2A | c.2036T>G p.V679G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1254132684; called by muse, mutect2, varscan2
- FGFR2 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV60651530; called by muse, mutect2, varscan2
- RTCA | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767927227; called by muse, mutect2, varscan2
- SSH1 | c.2801G>A p.R934Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs1478632697, COSV100425448; called by muse, mutect2, varscan2
- TRERF1 | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs762778385, COSV61671651; called by muse, mutect2, varscan2
- DNAJB6 | c.567_583del p.K189Nfs*2 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, varscan2
- ESRRG | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM187B | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LAMA1 | c.5659A>T p.S1887C | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MRPL4 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SORL1 | c.2836A>T p.I946F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- WDHD1 | c.2707G>A p.V903I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALG9 | c.1000C>T p.L334= | Silent (SNP) | VAF 96/196 reads (49%) | called by muse, mutect2, varscan2
- ATXN1 | c.1284C>G p.L428= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as rs745328393, COSV55208829, COSV55216723; called by muse, mutect2, varscan2
- CFAP251 | c.1374A>G p.L458= | Silent (SNP) | VAF 60/103 reads (58%) | called by muse, mutect2, varscan2
- FASTKD3 | c.1962A>G p.Q654= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1423019770; called by muse, varscan2
- GASK1B | c.1065T>C p.G355= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs1205717948; called by muse, mutect2, varscan2
- SLC28A3 | c.1941G>T p.L647= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs921347526; called by muse, mutect2, varscan2
- TRIM15 | c.471G>A p.V157= | Silent (SNP) | VAF 106/154 reads (69%) | called by muse, mutect2
